PECGS case C083-000024 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/f1c85d3d-1efc-4987-b54a-ca2a3004b439

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 38 years; Year of birth: 1981; Vital status: Dead; Cause of death: Cancer Related; Education level: Vocational College or Some College.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; Tissue or organ of origin: Appendix; Age at diagnosis: 38.4 years (14,026 days); AJCC pathologic stage: Stage IIIB; Progression or recurrence: yes; Days to last follow up: 945 days (2.6 years).

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000024_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000024_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
